Gene-level copy-number profile of tumor specimen C3N-03484-02 from CPTAC case C3N-03484, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,570 days).
Specimen C3N-03484-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0bde3517-4359-49e3-b479-9aa9ed1e4b0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03484-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/2a75d13c-ee7d-4a8c-bca9-3410e4d3d97a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 1; copy number 2: 3,729; copy number 3: 615; copy number 4: 45,687; copy number 5: 2,351; copy number 6: 5,878; copy number 7: 5; copy number 8: 41; copy number 9: 2; copy number 21: 9; copy number 172: 7.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,967,239–22,128,103, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:36,854,827–37,175,428, 9 genes, copy number 21: PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1.
- chr7:54,933,699–55,344,958, 7 genes, copy number 172: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr19:20,432,552–20,571,095, 2 genes, copy number 9 (within-gene range 6–9): AC008554.1, BNIP3P23.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
